Surgical pathology report (de-identified scan), TCGA case TCGA-VG-A8LO, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Institute of Human Virology Nigeria, specimen TCGA-VG-A8LO-01A (Primary Tumor).

[page 1 of 2]
Age:

Sex: Female

Tissue Source Site (TSS):

Date of Tumour Procurement:

ICD 0.3
Cystadenocarcinoma, papillary
series 846013
Site: C56.9
JW 4/4/14

1. **GROSS ASSESSMENT:** Cut section showed a grey tumour. Part of the deep resection margin is involved. 3.5x2.2x1.8cm

2. MICROSCOPIC ASSESSMENT

Microscopic description: Section shows a malignant tumour growing solid nests and papillary patterns. It is composed of large cells having moderately pleomorphic hyperchromatic nuclei and amphophilic cytoplasm. There are areas of cystic degeneration. The stroma is desmoplastic containing similar tumour cells and aggregates of lymphocytes. Focal areas of necrosis noted.

3. **Tumour Type:** Malignant
4. **Tumour Site:** Ovary
5. **Distance of invasive carcinoma to closest margin:** -
- Which margin?

[page 2 of 2]
TSS Unique patient ID:

6. HISTOLOGICAL DIAGNOSIS: Serous Papillary Cystadenocarcinoma

7. COMMENTS:

Reporting Pathologist Name

Signature

Date

Source: NCI Genomic Data Commons file 4009762e-51cf-461f-b29c-47a65abeac56 (TCGA-VG-A8LO.6FF4C359-F127-44E6-A1A2-641D60A3665F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).